TCGA case TCGA-RS-A6TO — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of mouth; Tissue source site: Memorial Sloan Kettering Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b815fae9-c595-4c76-acc6-6d38b9af9578

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 82 years; Vital status: Dead; Days to death: 387 days (1.1 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, keratinizing, NOS (the primary disease): ICD-O-3 morphology code: 8071/3; ICD-10 code: C06.9; Tissue or organ of origin: Mouth, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 82.4 years (30,104 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC clinical T: T4; AJCC clinical N: N2c; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4; AJCC pathologic N: N2c; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: Microscopic Extension; Lymph nodes positive: 4; Lymph nodes tested: 61; Lymphatic invasion present: No; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: No.
   Pathology details: Lymph node dissection method: Modified Radical Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Cetuximab; Days to treatment start: 41 days; Days to treatment end: 41 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 48 days; Days to treatment end: 94 days; Treatment dose: 7,000 cGy; Treatment outcome: Complete Response; Number of fractions: 35; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Cure; Days to treatment end: 94 days; Treatment outcome: No Measurable Disease.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, keratinizing, NOS), site: Floor of mouth, NOS. Age at diagnosis: 83.3 years (30,442 days); Days to diagnosis: 338 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 272 days; Disease response: Tumor Free.
- Day 338 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Floor of mouth, NOS; Days to recurrence: 338 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 387 days (1.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A: Negative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RS-A6TO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 550 mg.
  Slide TCGA-RS-A6TO-01A-03-TSC: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 29; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 6.
  Slide TCGA-RS-A6TO-01A-01-TSA: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 55; Percent stromal cells: 20; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-RS-A6TO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RS-A6TO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Anatomic organ subdivision: Oral Cavity; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Positive; Lymphovascular invasion: No; Tobacco smoking history indicator: 1; Alcohol history documented: No; Treatment outcome first course: Complete Remission/Response.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Radiation; Definitive treatment evidence disease after: No; Cause of death: Related to Head & Neck Cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 387 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 387 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 338 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RS-A6TO-01A-32D-A34I-01): tumor purity 0.42, ploidy 3.57, whole-genome doublings 1.
